Somatic mutation profile of tumor specimen ALCH-AE78-TTP1-A (aliquot ALCH-AE78-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AE78, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.5 years (21,001 days).
Specimen ALCH-AE78-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5780fc99-50b6-46a8-a504-8d0fc187bec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE78-NB1-A (Blood Derived Normal), aliquot ALCH-AE78-NB1-A-2-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d17620c6-2502-4b26-9e34-c59eab8e0dc1

The open-access MAF lists 707 somatic variants for this specimen: 495 protein-altering or splice-affecting, 129 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 424, Silent 129, Intron 40, Nonsense Mutation 39, 5'UTR 13, Frame Shift Del 12, RNA 11, Splice Site 11, 3'UTR 10, Splice Region 6, 5'Flank 6, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 209/398 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- ABL2 | c.1777G>C p.E593Q (on ENST00000502732 / NM_007314.4; = p.E578Q on NM_005158.5) | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV61016946; called by muse, mutect2, varscan2
- AC131160.1 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 34/1076 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312993353, COSV57700025; called by muse, mutect2
- ACTBL2 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 192/346 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.167); catalogued as COSV70660951; called by muse, mutect2, varscan2
- ACTN2 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 160/529 reads (30%) | catalogued as COSV63977619; called by muse, mutect2, varscan2
- ADAMTSL5 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57861184; called by muse, mutect2, varscan2
- ADD2 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100036769, COSV52464540; called by muse, mutect2, varscan2
- AFF3 | c.3336G>T p.K1112N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57853771; called by muse, mutect2, varscan2
- AGPAT5 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53447228; called by muse, mutect2, varscan2
- AKAP17A | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs193269079; called by muse, mutect2, varscan2
- ANXA3 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53716473; called by muse, mutect2, varscan2
- APOBR | c.57+3G>A | Splice Region (SNP) | VAF 23/97 reads (24%) | catalogued as rs759879470; called by muse, mutect2, varscan2
- APOC3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1036257870; called by muse, mutect2, varscan2
- ASNSD1 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53624195; called by muse, mutect2, varscan2
- ATXN2 | c.1757C>G p.S586C (on ENST00000550104; = p.S426C on NM_002973.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs769328663, COSV66480907; called by muse, mutect2, varscan2
- B3GALT1 | c.480G>C p.M160I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59908227; called by muse, mutect2
- BEST3 | c.686G>T p.W229L | Missense Mutation (SNP) | VAF 164/570 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100437777; called by muse, mutect2, varscan2
- BFAR | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs747180270; called by muse, mutect2, varscan2
- BRAT1 | c.1135-1G>A p.X379_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as rs1470556890; called by muse, mutect2, varscan2
- BRINP2 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 23/652 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64179320; called by muse, mutect2
- BRINP3 | c.1589G>C p.R530P | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66513875; called by muse, mutect2, varscan2
- BRWD3 | c.1403T>A p.V468E | Missense Mutation (SNP) | VAF 74/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64753687; called by muse, mutect2, varscan2
- CARD6 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 16/258 reads (6%) | catalogued as COSV99621247, COSV99621277; called by muse, mutect2
- CCDC15 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1195396105; called by muse, mutect2
- CCDC183 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 50/263 reads (19%) | catalogued as rs1418809173, COSV51566880, COSV51567474; called by muse, mutect2, varscan2
- CEP290 | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100470237; called by muse, mutect2, varscan2
- CEP95 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs782534703; called by muse, mutect2, varscan2
- CFAP46 | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1026005875; called by muse, mutect2, varscan2
- CFAP94 | c.1085C>G p.S362C (on ENST00000320267 / NM_001352064.2; = p.S368C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.482); catalogued as COSV57236975; called by muse, mutect2, varscan2
- CGNL1 | c.1863A>G p.I621M | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs766086814; called by muse, mutect2, varscan2
- CLCA4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs372259034; called by muse, mutect2
- CLUAP1 | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58894590, COSV58895147; called by muse, mutect2, varscan2
- CNTLN | c.4175del p.K1392Rfs*3 | Frame Shift Del (DEL) | VAF 29/201 reads (14%) | catalogued as rs747411468; called by mutect2, pindel, varscan2
- COL22A1 | c.3746G>T p.G1249V | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279111; called by muse, mutect2, varscan2
- COPB1 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 70/505 reads (14%) | catalogued as COSV51447863; called by muse, mutect2, varscan2
- CPAMD8 | c.3517G>A p.V1173I (on ENST00000651564; = p.V1126I on NM_015692.5) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs367994692; called by muse, mutect2, varscan2
- CR2 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 153/454 reads (34%) | catalogued as COSV65509338; called by muse, mutect2, varscan2
- CSF2RA | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs762479130, COSV62626873; called by muse, mutect2, varscan2
- CSNK1E | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs572744706, COSV100725104; called by muse, mutect2, varscan2
- CUL7 | c.2271G>T p.K757N | Missense Mutation (SNP) | VAF 552/1367 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54820702; called by muse, mutect2, varscan2
- CUL9 | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52728867; called by muse, mutect2
- CWF19L2 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs540647484; called by muse, mutect2, varscan2
- CYB561 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 181/426 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62539556; called by muse, mutect2, varscan2
- CYP26C1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as COSV99606085; called by muse, mutect2, varscan2
- DCC | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 103/590 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs779661533; called by muse, mutect2, varscan2
- DGKB | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1290899001; called by muse, mutect2, varscan2
- DISP1 | c.4234A>T p.K1412* | Nonsense Mutation (SNP) | VAF 150/383 reads (39%) | catalogued as COSV99451068; called by muse, mutect2, varscan2
- DNAI2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV56757238; called by muse, mutect2, varscan2
- DNAJB8 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1045184794; called by muse, mutect2
- DST | c.16522G>A p.E5508K (on ENST00000361203 / NM_001374722.1; = p.E3096K on NM_015548.5) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1418808051, COSV99758389; called by muse, mutect2, varscan2
- DYNC2H1 | c.12826G>A p.E4276K | Missense Mutation (SNP) | VAF 47/513 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV100520007; called by muse, mutect2
- EPB41L4A | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185548416; called by muse, mutect2, varscan2
- EZHIP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1398919199; called by muse, mutect2, varscan2
- FADS2 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53902221; called by muse, mutect2, varscan2
- FAT1 | c.9808A>G p.I3270V | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1177837114; called by muse, mutect2, varscan2
- FBL | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55683568; called by muse, mutect2
- FBXL7 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.194); catalogued as rs1561195951, COSV100311181, COSV61647642; called by muse, mutect2, varscan2
- FLT1 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 167/705 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56728249; called by muse, mutect2, varscan2
- GABRG2 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.581); catalogued as COSV62718947; called by muse, mutect2, varscan2
- GATA2 | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.43); catalogued as COSV62005408, COSV62007090; called by muse, mutect2, varscan2
- GLI2 | c.2461G>T p.A821S (on ENST00000361492 / NM_001374353.1; = p.A838S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs749423913; called by muse, mutect2, varscan2
- GOLGA7B | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs766490550, COSV54004771; called by muse, mutect2, varscan2
- GPATCH8 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs1225837014; called by muse, mutect2, varscan2
- GPR52 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV52300004; called by muse, mutect2, varscan2
- GRID1 | c.2162G>A p.C721Y | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.602); catalogued as rs1225500122; called by muse, mutect2, varscan2
- GTF2H1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs993755814; called by muse, mutect2
- GTF3C1 | c.3293+1G>T p.X1098_splice | Splice Site (SNP) | VAF 35/140 reads (25%) | catalogued as rs781686667; called by muse, mutect2, varscan2
- HEPH | c.3175C>A p.L1059I (on ENST00000343002; = p.L792I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs775723129; called by muse, mutect2, varscan2
- HEYL | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65721818, COSV65721859; called by muse, mutect2, varscan2
- HMG20A | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 70/487 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100287734, COSV60313670; called by muse, mutect2, varscan2
- HNF4G | c.824A>G p.N275S (on ENST00000354370 / NM_001330561.2; = p.N322S on NM_004133.5) | Missense Mutation (SNP) | VAF 72/785 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs767411990; called by muse, mutect2
- IFT122 | c.1894G>A p.E632K (on ENST00000348417 / NM_052989.3; = p.E573K on NM_018262.4) | Missense Mutation (SNP) | VAF 67/616 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.437); catalogued as COSV56203772; called by muse, mutect2, varscan2
- IGDCC3 | c.2124C>A p.D708E | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV60077916; called by muse, mutect2, varscan2
- IL6 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488521608, COSV51732131; called by muse, mutect2, varscan2
- ITGA8 | c.1120C>G p.P374A | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV65229567; called by muse, mutect2, varscan2
- KCNQ5 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59683816; called by muse, mutect2, varscan2
- KDM2A | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58188301; called by muse, mutect2, varscan2
- KLHL26 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1403526058, COSV99963342; called by muse, mutect2, varscan2
- KMT2E | c.4822C>T p.H1608Y | Missense Mutation (SNP) | VAF 287/880 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs763682009; called by muse, mutect2, varscan2
- LAMB4 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 67/269 reads (25%) | catalogued as COSV52713973; called by muse, mutect2, varscan2
- LARP4B | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 71/509 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100295787; called by muse, mutect2, varscan2
- LCMT2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59790266, COSV59791524; called by muse, mutect2, varscan2
- LCP2 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV50447424; called by muse, mutect2, varscan2
- LRRC7 | c.2408C>A p.T803N (on ENST00000651989 / NM_001370785.2; = p.T770N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.817); catalogued as rs757203769, COSV50459545; called by muse, mutect2, varscan2
- LSP1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs147990493; called by muse, mutect2
- MAN1A1 | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 57/266 reads (21%) | catalogued as COSV63781388; called by muse, mutect2, varscan2
- MAOB | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65206615; called by muse, mutect2, varscan2
- MEIS1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 61/606 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55491764; called by muse, mutect2, varscan2
- MKRN3 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV58810344; called by muse, mutect2, varscan2
- MPRIP | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV104401277; called by muse, mutect2, varscan2
- MS4A14 | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 70/535 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.099); catalogued as COSV100280330; called by muse, mutect2, varscan2
- MTMR8 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV100878384; called by muse, mutect2, varscan2
- MTPAP | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 81/637 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53932469; called by muse, mutect2, varscan2
- MUC16 | c.29438C>A p.A9813E | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs372516683; called by muse, mutect2, varscan2
- MUC16 | c.26511G>C p.E8837D | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV67492223; called by muse, mutect2, varscan2
- MUC4 | c.10366C>A p.P3456T | Missense Mutation (SNP) | VAF 90/1081 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.65); catalogued as rs767931138; called by muse, mutect2
- MYCBP2 | c.3176C>T p.P1059L (on ENST00000357337; = p.P1097L on NM_015057.5) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs775922416, COSV100631363; called by muse, mutect2, varscan2
- MYLK | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 154/668 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs140636141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.3358C>G p.Q1120E | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs201504369; called by muse, mutect2
- MYT1L | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 74/611 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NELL1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1475885063; called by muse, mutect2, varscan2
- NLRP7 | c.977A>T p.E326V | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146193856, COSV60174887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NODAL | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 75/716 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755850269; called by muse, mutect2, varscan2
- NT5C1B | c.1203C>T p.G401= (on ENST00000359846 / NM_001199086.2; = p.G341= on NM_033253.4) | Splice Region (SNP) | VAF 205/659 reads (31%) | catalogued as rs1243731006; called by muse, mutect2, varscan2
- OGT | c.2439C>G p.I813M | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65479913; called by muse, mutect2, varscan2
- OR10G8 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV70908792; called by muse, mutect2, varscan2
- OR14J1 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV65845892; called by muse, mutect2
- OR2B3 | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs765713429; called by muse, mutect2, varscan2
- OR4A15 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV59036488; called by muse, mutect2, varscan2
- OR5B2 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100222965; called by muse, mutect2, varscan2
- OR5I1 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV56888051; called by muse, mutect2
- OR5K3 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV101051661, COSV67349696; called by muse, mutect2
- PABPC3 | c.1740G>T p.L580F | Missense Mutation (SNP) | VAF 92/649 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99879758; called by muse, mutect2, varscan2
- PADI1 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64937988; called by muse, mutect2, varscan2
- PCDH18 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446056995; called by muse, mutect2, varscan2
- PCDHA4 | c.101C>G p.S34W | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); catalogued as COSV63545789; called by muse, mutect2, varscan2
- PCDHB6 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 96/488 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1554277843, COSV50706023, COSV50706653; called by muse, mutect2, varscan2
- PDCL | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 172/445 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1203554224; called by mutect2, varscan2
- PDE6D | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV55020150; called by muse, mutect2, varscan2
- PDXDC1 | c.1202C>G p.S401* | Nonsense Mutation (SNP) | VAF 36/533 reads (7%) | catalogued as COSV57909623; called by muse, mutect2
- PDYN | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 166/463 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV99453322; called by muse, mutect2, varscan2
- PEAR1 | c.594C>A p.C198* | Nonsense Mutation (SNP) | VAF 59/330 reads (18%) | catalogued as COSV52775403; called by muse, mutect2, varscan2
- PKHD1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 60/704 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs767379405, COSV61899121; ClinVar: uncertain significance; called by muse, mutect2
- PLA1A | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 124/509 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99846111; called by muse, mutect2, varscan2
- PLCH1 | c.2938G>T p.A980S (on ENST00000340059 / NM_001130960.2; = p.A972S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.114); catalogued as COSV58187451; called by muse, mutect2, varscan2
- PLEKHA8 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV51650218, COSV99321907; called by muse, mutect2, varscan2
- PNN | c.1688G>C p.R563T | Missense Mutation (SNP) | VAF 76/514 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV53767094, COSV99397112; called by muse, mutect2, varscan2
- POFUT2 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100499526; called by muse, mutect2, varscan2
- POLD1 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV70954390; called by muse, mutect2
- POM121L12 | c.576C>A p.F192L | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV68692173; called by muse, mutect2
- PPP2R1A | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59045222; called by muse, varscan2
- PPP4R4 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428418, COSV58554806; called by muse, mutect2, varscan2
- PPRC1 | c.2734G>C p.D912H | Missense Mutation (SNP) | VAF 46/377 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.921); catalogued as rs1564943928; called by muse, mutect2, varscan2
- PTGIR | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs771919888; called by muse, varscan2
- PTOV1 | c.804+3G>A | Splice Region (SNP) | VAF 107/321 reads (33%) | catalogued as rs1285869537; called by muse, mutect2, varscan2
- PTPRT | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs951863604, COSV62023449; called by muse, mutect2, varscan2
- PXK | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 148/421 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1224681951; called by muse, mutect2, varscan2
- RASL10B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 27/432 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs782493239; called by muse, mutect2
- RGL1 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 41/280 reads (15%) | catalogued as COSV58979847; called by muse, mutect2, varscan2
- RPRM | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375987189; called by muse, mutect2, varscan2
- S100A11 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 58/489 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs754870480; called by muse, mutect2, varscan2
- SAGE1 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 129/319 reads (40%) | catalogued as COSV61015216; called by muse, mutect2, varscan2
- SIGLEC10 | c.1278C>A p.H426Q | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV59483681, COSV59484019; called by muse, mutect2, varscan2
- SLC12A3 | c.2081A>T p.N694I | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV52638673; called by muse, mutect2, varscan2
- SLC25A25 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1458855169; called by muse, mutect2, varscan2
- SLC26A4 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1037267548; called by muse, mutect2, varscan2
- SLC5A10 | c.1468G>C p.E490Q (on ENST00000395645 / NM_001042450.4; = p.E506Q on NM_152351.5) | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52413179; called by muse, mutect2
- SLC9A2 | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.049); catalogued as rs544365552, COSV52129852; called by muse, mutect2, varscan2
- SNURF | c.15-1G>C p.X5_splice | Splice Site (SNP) | VAF 188/763 reads (25%) | catalogued as COSV57596949; called by muse, mutect2, varscan2
- SOS1 | c.2961C>G p.I987M | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV101217279; called by muse, mutect2, varscan2
- SRGAP1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs770426933, COSV100754444, COSV61905154; called by muse, mutect2, varscan2
- SRSF2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | catalogued as COSV57974905; called by muse, mutect2
- ST18 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52505173, COSV52512181; called by muse, mutect2
- STRC | c.4882T>C p.C1628R | Missense Mutation (SNP) | VAF 88/601 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760304841, CM165451; called by muse, mutect2, varscan2
- SUPT6H | c.1209G>T p.W403C | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166594985; called by muse, mutect2, varscan2
- SUSD1 | c.2195C>A p.S732Y | Missense Mutation (SNP) | VAF 56/431 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62582324; called by muse, mutect2, varscan2
- TASOR2 | c.4861G>T p.G1621C | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs778354641; called by mutect2, varscan2
- TBC1D12 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 69/560 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs763853711, COSV56554077; called by muse, mutect2, varscan2
- TCEAL4 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs758997247; called by muse, mutect2, varscan2
- TDRD6 | c.4738G>C p.E1580Q | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.669); catalogued as COSV60173790; called by muse, mutect2
- TECTA | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs886047838, COSV50760249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.6910G>T p.A2304S | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1168410994, COSV69320199; called by muse, mutect2, varscan2
- TENT5D | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57637189; called by muse, mutect2, varscan2
- TERT | c.2831G>A p.S944N | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs759314942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGM5 | c.1936C>T p.L646F (on ENST00000220420 / NM_201631.4; = p.L564F on NM_004245.4) | Missense Mutation (SNP) | VAF 133/864 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs758924191; called by muse, mutect2, varscan2
- THSD4 | c.2800del p.V934Sfs*11 | Frame Shift Del (DEL) | VAF 35/243 reads (14%) | catalogued as COSV99965553; called by mutect2, pindel, varscan2
- TOPAZ1 | c.3431G>A p.R1144H | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV59067618; called by muse, mutect2, varscan2
- TOPBP1 | c.1259A>G p.H420R | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs771751235; called by muse, mutect2, varscan2
- TRAV29DV5 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs769958261; called by muse, mutect2, varscan2
- TRIM49C | c.57G>C p.M19I | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV101442195; called by mutect2, varscan2
- TRIP6 | c.1019C>G p.A340G | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV52341032; called by muse, mutect2, varscan2
- TRPC5 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); catalogued as COSV53303238; called by muse, mutect2, varscan2
- TTN | c.86056C>A p.P28686T (on ENST00000591111; = p.P21262T on NM_003319.4) | Missense Mutation (SNP) | VAF 48/222 reads (22%) | PolyPhen benign (0.154); catalogued as COSV60214260; called by muse, mutect2, varscan2
- TULP1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 314/643 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs1183134109, COSV57692653; called by muse, varscan2
- UBE3A | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 53/852 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV51661401; called by muse, mutect2
- UBQLN2 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100592716; called by muse, mutect2, varscan2
- UFL1 | c.1782G>C p.M594I | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV65150255, COSV65150848; called by muse, mutect2
- USH2A | c.11887G>A p.A3963T | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs541566194; called by muse, mutect2, varscan2
- USP17L3 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs906769079; called by mutect2, varscan2
- VSIG4 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV66073141; called by muse, mutect2, varscan2
- VWA5B1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 82/511 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57059079; called by muse, mutect2, varscan2
- ZFAT | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs767015633, COSV64745490; called by muse, mutect2, varscan2
- ZHX1 | c.2258G>C p.R753T | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV52876174; called by muse, mutect2, varscan2
- ZMAT1 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV65658235; called by muse, mutect2, varscan2
- ZNF208 | c.3251C>A p.P1084H | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1395480824, COSV101236900; called by muse, mutect2, varscan2
- ZNF354A | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100234368; called by muse, mutect2, varscan2
- ZNF568 | c.1580G>A p.S527N | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs776817872; called by muse, mutect2, varscan2
- ZNF691 | c.403C>T p.R135W (on ENST00000372502; = p.R104W on NM_015911.3) | Missense Mutation (SNP) | VAF 78/479 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368885981, COSV65289284; called by muse, mutect2, varscan2
- ZXDC | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 214/848 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1446274703; called by muse, mutect2, varscan2
- ABCA1 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 189/542 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ABCA12 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCA6 | c.255A>C p.L85F | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABCB1 | c.3338T>A p.L1113Q | Missense Mutation (SNP) | VAF 226/647 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCB1 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 136/614 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ACTR8 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS18 | c.2534T>C p.I845T | Missense Mutation (SNP) | VAF 81/546 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ADD2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, varscan2
- ADGRG7 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 140/619 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AK5 | c.679G>T p.A227S (on ENST00000354567 / NM_174858.3; = p.A201S on NM_012093.4) | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- AKAP1 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 161/430 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AKAP9 | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- ALG10 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 176/733 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALG13 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 52/379 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMER3 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AMIGO3 | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOTL2 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, varscan2
- ANK2 | c.3922C>A p.Q1308K | Missense Mutation (SNP) | VAF 140/436 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ANK3 | c.9340G>T p.V3114L | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30A | c.2892C>G p.I964M (on ENST00000611781; = p.I908M on NM_052997.2) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ANKS6 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2
- AP000812.4 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- APC2 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 65/202 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1222A>T p.K408* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ARHGEF5 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 188/694 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ARMC4 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ART4 | c.633_634del p.L212Pfs*39 | Frame Shift Del (DEL) | VAF 52/236 reads (22%) | called by mutect2, pindel, varscan2
- ASGR2 | c.935G>T p.*312Lext*7 | Nonstop Mutation (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- ASMTL | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP10D | c.4010G>T p.R1337I | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ATP7A | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ATRX | c.6577C>T p.Q2193* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- B4GALT4 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 118/448 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); called by muse, varscan2
- BICDL2 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C1orf112 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 38/351 reads (11%) | called by muse, mutect2, varscan2
- C3orf52 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 76/691 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- C9orf24 | c.246C>G p.Y82* | Nonsense Mutation (SNP) | VAF 35/301 reads (12%) | called by muse, mutect2, varscan2
- CACNA1A | c.6564C>A p.S2188R | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, varscan2
- CACNA1E | c.3724G>C p.A1242P | Missense Mutation (SNP) | VAF 111/405 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CARMIL1 | c.3336G>T p.K1112N | Missense Mutation (SNP) | VAF 210/461 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CASQ2 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CASTOR2 | c.916C>G p.H306D | Missense Mutation (SNP) | VAF 344/974 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CATSPERE | c.1230C>A p.C410* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- CCDC39 | n.678T>A | Splice Region (SNP) | VAF 208/620 reads (34%) | called by muse, mutect2, varscan2
- CCL14 | c.82G>T p.G28* (on ENST00000618404 / NM_032963.4; = p.G44* on NM_032962.4) | Nonsense Mutation (SNP) | VAF 113/266 reads (42%) | called by muse, mutect2, varscan2
- CCT2 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 127/409 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD109 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CDON | c.2876C>G p.A959G | Missense Mutation (SNP) | VAF 123/680 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CEACAM20 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CEP126 | c.2729G>C p.R910T | Missense Mutation (SNP) | VAF 45/452 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2
- CFAP70 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CLCNKB | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNBD1 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 89/537 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNR2 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- COL11A1 | c.4367G>T p.G1456V | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 84/655 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COL2A1 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 93/761 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.1970A>C p.K657T | Missense Mutation (SNP) | VAF 113/498 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- COPG1 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CREBBP | c.4568T>G p.F1523C | Missense Mutation (SNP) | VAF 148/389 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CRIM1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CRYM | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 158/458 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CTNND2 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 21/479 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- CTTNBP2 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 271/754 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CWC25 | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CYP26B1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 83/616 reads (13%) | called by muse, mutect2, varscan2
- CYTH4 | c.844A>T p.I282F | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DAZAP1 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- DGKI | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGKZ | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2
- DIPK1A | c.1227G>C p.L409F | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLG2 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.3731G>C p.G1244A | Missense Mutation (SNP) | VAF 77/718 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH9 | c.4092G>T p.W1364C | Missense Mutation (SNP) | VAF 149/347 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DNAJB11 | c.425T>C p.L142S | Missense Mutation (SNP) | VAF 106/396 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK4 | c.3101T>G p.L1034* | Nonsense Mutation (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- DOK5 | c.84del p.W28Cfs*2 | Frame Shift Del (DEL) | VAF 52/295 reads (18%) | called by mutect2, pindel, varscan2
- DPY19L3 | c.1938G>T p.R646S | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DYRK4 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 45/395 reads (11%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 66/354 reads (19%) | called by muse, mutect2, varscan2
- EEF2 | c.1311del p.K438Rfs*7 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- EI24 | c.851del p.G284Afs*17 | Frame Shift Del (DEL) | VAF 41/294 reads (14%) | called by mutect2, pindel, varscan2
- EIF2A | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 130/534 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- EIF2S2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 149/432 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EIF4G1 | c.3269G>T p.R1090L (on ENST00000346169 / NM_198241.3; = p.R895L on NM_004953.5) | Missense Mutation (SNP) | VAF 194/1131 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EMC6 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- EPB41L3 | c.*7G>T | Splice Region (SNP) | VAF 63/324 reads (19%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2771G>T p.R924L | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- F5 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 52/580 reads (9%) | called by muse, mutect2
- FAM133A | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 38/572 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); called by muse, mutect2
- FAM155B | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM183A | c.395A>T p.H132L | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM184B | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM71B | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAR2 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 26/600 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2
- FASTK | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBXO33 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.188); called by muse, mutect2
- FECH | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FMN2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FN1 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXL3 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- FRMD4B | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); called by muse, mutect2
- GALNT8 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- GDA | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 118/304 reads (39%) | called by muse, mutect2, varscan2
- GIGYF1 | c.2606C>G p.S869* | Nonsense Mutation (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- GINM1 | c.513G>T p.L171F | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GK | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 77/351 reads (22%) | called by muse, mutect2, varscan2
- GK2 | c.658T>C p.C220R | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLM2 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 114/408 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GPM6A | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GPM6A | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR179 | c.4921G>T p.G1641W (on ENST00000621958; = p.G1640W on NM_001004334.4) | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR45 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPRC6A | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GREM2 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK1 | c.2045C>A p.P682H | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM3 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.2685del p.S898Vfs*10 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | called by mutect2, pindel, varscan2
- GRM8 | c.2678-2A>T p.X893_splice | Splice Site (SNP) | VAF 97/305 reads (32%) | called by muse, mutect2, varscan2
- HCN1 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 122/749 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, varscan2
- HEPH | c.3320T>C p.M1107T (on ENST00000343002; = p.M840T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/566 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, varscan2
- HERC1 | c.4997C>T p.S1666L | Missense Mutation (SNP) | VAF 50/831 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- HNRNPK | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HOXC5 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HRH2 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- HYDIN | c.6559C>A p.P2187T | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.292); called by muse, mutect2
- IGFBP1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- IGLV1-44 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- IL22 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- INSYN2A | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- INSYN2A | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- KCNH7 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KIF20B | c.5290G>A p.E1764K (on ENST00000371728 / NM_001284259.2; = p.E1724K on NM_016195.4) | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- KIN | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- KIRREL1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2
- KLHL17 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KLHL7 | c.977G>C p.R326P (on ENST00000339077 / NM_001031710.3; = p.R278P on NM_018846.5) | Missense Mutation (SNP) | VAF 72/490 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNDC1 | c.4962G>C p.Q1654H | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- KRT6B | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 93/772 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KRTAP5-9 | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 89/488 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LAMA1 | c.3688-1G>C p.X1230_splice | Splice Site (SNP) | VAF 142/702 reads (20%) | called by muse, mutect2, varscan2
- LCA5 | c.2093G>C p.*698Sext*13 | Nonstop Mutation (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- LGSN | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LILRA1 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- LRATD1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.639); called by muse, mutect2
- LRRC75A | c.330C>A p.H110Q | Missense Mutation (SNP) | VAF 159/411 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LTBP1 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 66/612 reads (11%) | called by muse, mutect2, varscan2
- LY75 | c.4810C>G p.Q1604E | Missense Mutation (SNP) | VAF 73/521 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MADD | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGED1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 128/336 reads (38%) | called by muse, mutect2, varscan2
- MAGEE1 | c.2503A>G p.N835D | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEOX2 | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 95/664 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.059); called by muse, varscan2
- MFSD6 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- MGAT4A | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MRGPRX3 | c.255A>T p.L85F | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MS4A4A | c.331-1G>T p.X111_splice | Splice Site (SNP) | VAF 50/340 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.41774C>A p.P13925Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); called by muse, varscan2
- MUC16 | c.29875del p.Q9959Kfs*38 | Frame Shift Del (DEL) | VAF 49/467 reads (10%) | called by mutect2, pindel, varscan2
- MUC5B | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- MUC5B | c.8906G>A p.G2969D | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYCBP2 | c.12449C>T p.S4150L (on ENST00000357337; = p.S4188L on NM_015057.5) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- MYH6 | c.4856A>T p.K1619M | Missense Mutation (SNP) | VAF 156/456 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH7 | c.3220C>T p.Q1074* | Nonsense Mutation (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- MYL6 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO1B | c.1385A>G p.E462G | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NBAS | c.3310A>G p.T1104A | Missense Mutation (SNP) | VAF 98/548 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBEA | c.6010G>A p.E2004K | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCBP3 | c.1769A>T p.Q590L | Missense Mutation (SNP) | VAF 310/807 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NDUFA9 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NHSL2 | c.158C>T p.S53F (on ENST00000510661; = p.S419F on NM_001013627.2) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- NLGN1 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 85/811 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NOD2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOTCH1 | c.3359G>T p.G1120V | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NPAS4 | c.1105G>C p.A369P | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHS1 | c.3278T>C p.L1093P | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRCAM | c.2626G>T p.G876* (on ENST00000379028 / NM_001371124.1; = p.G860* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 163/340 reads (48%) | called by muse, mutect2, varscan2
- NRIP2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NRXN2 | c.3434G>T p.G1145V | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NUDT13 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUFIP1 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.072); called by muse, varscan2
- OCA2 | c.2339-1G>A p.X780_splice | Splice Site (SNP) | VAF 73/635 reads (11%) | called by muse, mutect2, varscan2
- OLFM1 | c.634T>C p.S212P (on ENST00000371793 / NM_001282611.2; = p.S194P on NM_014279.5) | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- OPLAH | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- OPN5 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 187/478 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G4 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR1F1 | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OR4D9 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, varscan2
- OR51D1 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR52D1 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 60/379 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR52K2 | c.848del p.L283Rfs*10 | Frame Shift Del (DEL) | VAF 41/335 reads (12%) | called by mutect2, pindel, varscan2
- OR8H1 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OSBPL5 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSMR | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 155/712 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PABPC1L | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAK3 | c.524C>G p.T175R (on ENST00000262836 / NM_001324328.2; = p.T160R on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/526 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3B | c.507T>G p.D169E | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PARP6 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHGA6 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PCDHGB1 | c.2211del p.N738Tfs*29 | Frame Shift Del (DEL) | VAF 116/390 reads (30%) | called by mutect2, pindel, varscan2
- PCNX2 | c.4708G>C p.E1570Q | Missense Mutation (SNP) | VAF 41/450 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PDE2A | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- PGAM1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PHLDB2 | c.2200A>T p.S734C (on ENST00000393925 / NM_001134439.2; = p.S691C on NM_145753.2) | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHRF1 | c.3806A>T p.H1269L (on ENST00000264555 / NM_001286581.2; = p.H1268L on NM_020901.4) | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIEZO2 | c.4586A>C p.K1529T | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PIEZO2 | c.3633G>A p.W1211* | Nonsense Mutation (SNP) | VAF 88/403 reads (22%) | called by muse, mutect2, varscan2
- PJA2 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 74/252 reads (29%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); called by muse, mutect2
- PLEKHA3 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PODNL1 | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POLN | c.2362G>C p.A788P | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- POTEB3 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 44/503 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP3R2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 86/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAMEF12 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRAMEF7 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRSS35 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG8 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PTGIR | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PTPN11 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 180/691 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN6 | c.1695G>C p.E565D | Missense Mutation (SNP) | VAF 86/985 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2
- PTPRN2 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2
- PTPRO | c.927T>G p.S309R | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PXDNL | c.3828A>T p.E1276D | Missense Mutation (SNP) | VAF 58/677 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- RALGAPB | c.952A>T p.M318L | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM10 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 190/442 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, varscan2
- RBM42 | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RECK | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- RETREG1 | c.471C>G p.I157M (on ENST00000306320 / NM_001034850.2; = p.I16M on NM_019000.4) | Missense Mutation (SNP) | VAF 83/908 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2
- RTL3 | c.46A>T p.N16Y | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCG2 | c.492G>C p.M164I | Missense Mutation (SNP) | VAF 147/478 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SCN5A | c.3349C>G p.Q1117E (on ENST00000333535 / NM_198056.3; = p.Q1116E on NM_000335.5) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCYL2 | c.1717C>G p.H573D | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2
- SEMA5A | c.2572G>T p.G858C | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP7 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- SERPINA5 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SGCE | c.1350G>T p.M450I (on ENST00000647096; = p.M414I on NM_003919.3) | Missense Mutation (SNP) | VAF 261/804 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SGO2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SH2B2 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SH3KBP1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIX1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SLC12A1 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.871); called by muse, varscan2
- SLC16A1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 75/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC32A1 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC33A1 | c.1209A>T p.Q403H | Missense Mutation (SNP) | VAF 98/489 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SLC38A5 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK4 | c.2389G>C p.G797R | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SMC1B | c.1293T>A p.H431Q | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SMC4 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 52/530 reads (10%) | called by muse, mutect2
- SMG7 | c.3026C>G p.P1009R | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNTG1 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SNX14 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 36/394 reads (9%) | called by muse, mutect2
- SORCS3 | c.3046C>G p.P1016A | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SP140 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 78/240 reads (33%) | called by muse, mutect2, varscan2
- SPON1 | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STARD3 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- STRN3 | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 66/547 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT16H | c.67-1G>T p.X23_splice | Splice Site (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- SYNE1 | c.2005G>C p.E669Q (on ENST00000367255 / NM_182961.4; = p.E676Q on NM_033071.3) | Missense Mutation (SNP) | VAF 62/475 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF7L | c.1285-1G>T p.X429_splice | Splice Site (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 53/335 reads (16%) | called by muse, mutect2, varscan2
- TBC1D9 | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TCHH | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEP1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- TMEM177 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TMEM267 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 119/799 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- TOX | c.927C>A p.V309= | Splice Region (SNP) | VAF 92/272 reads (34%) | called by muse, varscan2
- TPTE2 | c.956A>T p.H319L (on ENST00000400230 / NM_199254.2; = p.H242L on NM_130785.3) | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPX2 | c.1510-2A>C p.X504_splice | Splice Site (SNP) | VAF 11/96 reads (11%) | called by muse, varscan2
- TRIB2 | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 125/911 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM60 | c.993G>C p.R331S | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIP12 | c.1000A>G p.S334G | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TRMT2B | c.244del p.E82Kfs*7 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | called by mutect2, pindel, varscan2
- TTBK1 | c.3482G>T p.G1161V | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); called by muse, mutect2
- TTC23 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.100061G>C p.G33354A (on ENST00000591111; = p.G25930A on NM_003319.4) | Missense Mutation (SNP) | VAF 110/695 reads (16%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.30876G>C p.K10292N (on ENST00000591111; = p.K9365N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/354 reads (13%) | PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TTN | c.17027C>T p.A5676V (on ENST00000591111; = p.A4749V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/284 reads (20%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC79 | c.7261G>T p.G2421C (on ENST00000393151 / NM_001346218.2; = p.G2244C on NM_020818.5) | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP34 | c.9180G>C p.L3060F | Missense Mutation (SNP) | VAF 39/950 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); called by muse, mutect2
- WASHC5 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.708); called by muse, mutect2
- WDPCP | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 455/996 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, varscan2
- WDPCP | c.1480_1489del p.Q494Tfs*9 | Frame Shift Del (DEL) | VAF 312/938 reads (33%) | called by pindel, varscan2
- WIPI1 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 110/544 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WNK2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- XIRP2 | c.9614C>A p.S3205Y (on ENST00000628543; = p.S3380Y on NM_152381.6) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- YDJC | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YTHDC1 | c.921A>G p.I307M | Missense Mutation (SNP) | VAF 21/481 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ZBTB7C | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZHX3 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZIC5 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF132 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ZNF320 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF33A | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, varscan2
- ZNF414 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF460 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2
- ZNF480 | c.1187A>T p.E396V | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF485 | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF512 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF649 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF714 | c.1289G>T p.C430F | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ZNF804B | c.1316A>G p.K439R | Missense Mutation (SNP) | VAF 114/565 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZP2 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZSCAN4 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- ZSCAN4 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZXDC | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZZEF1 | c.3526C>T p.H1176Y | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ABCC2 | c.2007G>C p.V669= | Silent (SNP) | VAF 110/818 reads (13%) | called by muse, mutect2, varscan2
- ADCY3 | c.933C>T p.Y311= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as rs1454726873; called by muse, mutect2
- ADGRB1 | c.2394C>A p.A798= | Silent (SNP) | VAF 40/407 reads (10%) | called by muse, mutect2
- AMBN | c.1041T>A p.P347= | Silent (SNP) | VAF 149/526 reads (28%) | called by muse, mutect2, varscan2
- ANKRD12 | c.2571A>G p.K857= | Silent (SNP) | VAF 70/285 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.207A>G p.Q69= | Silent (SNP) | VAF 156/670 reads (23%) | catalogued as rs1324572546; called by muse, mutect2, varscan2
- ARHGEF3 | c.603C>T p.L201= | Silent (SNP) | VAF 47/340 reads (14%) | catalogued as rs371546890; called by muse, mutect2, varscan2
- ASAP2 | c.2388G>A p.Q796= | Silent (SNP) | VAF 280/777 reads (36%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.2538A>T p.S846= | Silent (SNP) | VAF 157/389 reads (40%) | catalogued as rs371549721; called by muse, mutect2, varscan2
- C12orf50 | c.1119C>G p.L373= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as rs758261617; called by muse, mutect2, varscan2
- C20orf194 | c.885C>T p.S295= | Silent (SNP) | VAF 186/638 reads (29%) | called by muse, mutect2, varscan2
- CAVIN1 | c.753C>T p.N251= | Silent (SNP) | VAF 99/712 reads (14%) | catalogued as rs868528569; called by muse, mutect2, varscan2
- CCDC39 | c.798C>A p.I266= | Silent (SNP) | VAF 150/493 reads (30%) | catalogued as COSV56495199, COSV99871024; called by muse, mutect2, varscan2
- CHRNA5 | c.882C>G p.V294= | Silent (SNP) | VAF 40/404 reads (10%) | catalogued as rs376254340; called by muse, mutect2
- CLCA2 | c.1875T>C p.Y625= | Silent (SNP) | VAF 69/590 reads (12%) | called by muse, mutect2, varscan2
- CNKSR1 | c.1170G>C p.R390= (on ENST00000374253 / NM_001297647.2; = p.R383= on NM_006314.3) | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- CNOT1 | c.1419C>T p.F473= | Silent (SNP) | VAF 52/410 reads (13%) | catalogued as rs202237421, COSV57767131; called by muse, mutect2, varscan2
- CRNKL1 | c.315C>G p.A105= | Silent (SNP) | VAF 42/410 reads (10%) | called by muse, mutect2
- CTNNA2 | c.2142G>T p.L714= | Silent (SNP) | VAF 44/296 reads (15%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2622T>C p.N874= (on ENST00000402739 / NM_001282597.3; = p.N826= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2
- CYP2C9 | c.261G>T p.L87= | Silent (SNP) | VAF 89/686 reads (13%) | catalogued as COSV53253266; called by muse, mutect2, varscan2
- DAAM2 | c.1413A>G p.T471= | Silent (SNP) | VAF 112/284 reads (39%) | called by muse, mutect2, varscan2
- DRAM2 | c.243G>C p.L81= | Silent (SNP) | VAF 26/368 reads (7%) | called by muse, mutect2
- DRD1 | c.984C>A p.P328= | Silent (SNP) | VAF 162/524 reads (31%) | called by muse, mutect2, varscan2
- DUT | c.300C>T p.P100= (on ENST00000331200 / NM_001025248.2; = p.P12= on NM_001948.4) | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100485187; called by muse, mutect2, varscan2
- EIF4G1 | c.3270A>T p.R1090= (on ENST00000346169 / NM_198241.3; = p.R895= on NM_004953.5) | Silent (SNP) | VAF 180/1094 reads (16%) | called by muse, varscan2
- ENPP4 | c.702T>C p.I234= | Silent (SNP) | VAF 54/944 reads (6%) | called by muse, mutect2
- ERBB4 | c.1098G>A p.L366= | Silent (SNP) | VAF 17/491 reads (3%) | catalogued as COSV53549859, COSV99627779; called by muse, mutect2
- FAM71E2 | c.1644G>A p.Q548= | Silent (SNP) | VAF 71/236 reads (30%) | called by muse, mutect2, varscan2
- FFAR3 | c.972T>A p.A324= | Silent (SNP) | VAF 125/509 reads (25%) | called by muse, mutect2, varscan2
- FMN2 | c.3117G>C p.A1039= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV60456341; called by muse, varscan2
- GABRR2 | c.570G>A p.Q190= | Silent (SNP) | VAF 63/457 reads (14%) | called by muse, mutect2, varscan2
- GANAB | c.1491C>T p.D497= | Silent (SNP) | VAF 56/306 reads (18%) | catalogued as rs1348604119; called by muse, mutect2, varscan2
- GAS8 | c.54C>T p.V18= | Silent (SNP) | VAF 51/426 reads (12%) | catalogued as rs185349515; called by muse, mutect2, varscan2
- GIMAP8 | c.1762C>A p.R588= | Silent (SNP) | VAF 192/471 reads (41%) | catalogued as rs770094053, COSV56230411; called by muse, mutect2, varscan2
- HECW1 | c.3459G>A p.R1153= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as COSV67835732; called by muse, mutect2
- HHLA2 | c.276A>C p.T92= | Silent (SNP) | VAF 48/431 reads (11%) | called by muse, mutect2, varscan2
- HTR1F | c.975T>G p.S325= | Silent (SNP) | VAF 32/240 reads (13%) | called by muse, varscan2
- IFI44L | c.1257C>G p.L419= | Silent (SNP) | VAF 36/301 reads (12%) | catalogued as rs1235756123; called by muse, mutect2, varscan2
- IL17F | c.84G>T p.A28= | Silent (SNP) | VAF 94/602 reads (16%) | catalogued as rs200098518; called by muse, mutect2, varscan2
- IL18RAP | c.669C>T p.Y223= | Silent (SNP) | VAF 48/455 reads (11%) | called by muse, mutect2
- IRGC | c.1038C>G p.L346= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- ISLR2 | c.1269C>G p.A423= | Silent (SNP) | VAF 40/368 reads (11%) | called by mutect2, varscan2
- KCNJ13 | c.372C>T p.T124= | Silent (SNP) | VAF 169/464 reads (36%) | called by muse, mutect2, varscan2
- KIF4A | c.366C>G p.L122= | Silent (SNP) | VAF 38/349 reads (11%) | called by muse, mutect2, varscan2
- KLHL18 | c.972A>C p.T324= | Silent (SNP) | VAF 131/377 reads (35%) | called by muse, mutect2, varscan2
- KRT72 | c.1014C>A p.L338= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs1166883886; called by muse, mutect2, varscan2
- KRT83 | c.736C>A p.R246= | Silent (SNP) | VAF 204/553 reads (37%) | catalogued as COSV53341542; called by muse, mutect2, varscan2
- LHX5 | c.621C>A p.R207= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, varscan2
- LIPH | c.1296C>G p.V432= | Silent (SNP) | VAF 101/787 reads (13%) | called by muse, mutect2, varscan2
- LPA | c.3357C>T p.P1119= | Silent (SNP) | VAF 17/374 reads (5%) | called by muse, mutect2
- LRRC38 | c.774G>T p.V258= | Silent (SNP) | VAF 79/545 reads (14%) | called by muse, mutect2, varscan2
- MAP2K1 | c.372G>T p.P124= | Silent (SNP) | VAF 213/662 reads (32%) | catalogued as COSV61070506; called by muse, mutect2, varscan2
- MDH2 | c.963C>T p.P321= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as rs781841137, COSV59883849; called by muse, mutect2
- MED12 | c.4059G>A p.Q1353= | Silent (SNP) | VAF 65/545 reads (12%) | called by muse, mutect2, varscan2
- MMP12 | c.132G>A p.E44= | Silent (SNP) | VAF 38/190 reads (20%) | called by muse, varscan2
- MUC16 | c.34188C>G p.V11396= | Silent (SNP) | VAF 92/273 reads (34%) | called by muse, mutect2, varscan2
- MYBL2 | c.1143G>A p.L381= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- NBPF9 | c.66G>A p.E22= | Silent (SNP) | VAF 82/690 reads (12%) | catalogued as rs782031247; called by muse, mutect2, varscan2
- NFKB1 | c.2826G>C p.L942= (on ENST00000394820 / NM_001382627.1; = p.L943= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/320 reads (8%) | called by muse, mutect2
- NLRP3 | c.2157G>A p.V719= | Silent (SNP) | VAF 78/734 reads (11%) | catalogued as rs201515412, COSV60224297; called by muse, mutect2, varscan2
- NLRP4 | c.579G>C p.L193= | Silent (SNP) | VAF 79/287 reads (28%) | called by muse, mutect2, varscan2
- NOA1 | c.1062C>G p.L354= | Silent (SNP) | VAF 81/279 reads (29%) | called by muse, mutect2, varscan2
- NUBPL | c.690G>T p.V230= | Silent (SNP) | VAF 131/557 reads (24%) | called by muse, mutect2, varscan2
- OR10G2 | c.279C>A p.S93= | Silent (SNP) | VAF 140/398 reads (35%) | called by muse, mutect2, varscan2
- OR5L1 | c.867C>A p.I289= | Silent (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
- OR5T1 | c.609C>T p.D203= | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- OR9G1 | c.771C>A p.I257= | Silent (SNP) | VAF 26/380 reads (7%) | catalogued as COSV100380285; called by muse, mutect2
- OTOG | c.6426A>T p.P2142= | Silent (SNP) | VAF 33/188 reads (18%) | called by muse, mutect2, varscan2
- PABPC1L | c.252C>T p.I84= | Silent (SNP) | VAF 36/204 reads (18%) | called by muse, mutect2, varscan2
- PADI6 | c.939G>T p.V313= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4098G>T p.S1366= | Silent (SNP) | VAF 69/665 reads (10%) | catalogued as COSV62814247; called by muse, mutect2, varscan2
- PDE10A | c.453T>A p.P151= | Silent (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2, varscan2
- PEX1 | c.1080G>A p.Q360= | Silent (SNP) | VAF 54/704 reads (8%) | called by muse, mutect2
- PEX10 | c.684G>C p.L228= | Silent (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- PGAM4 | c.414G>A p.K138= | Silent (SNP) | VAF 66/581 reads (11%) | called by muse, mutect2, varscan2
- PLXNC1 | c.879G>A p.L293= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- POTEB3 | c.936T>G p.A312= | Silent (SNP) | VAF 43/502 reads (9%) | called by muse, mutect2, varscan2
- PRKDC | c.11700C>G p.L3900= | Silent (SNP) | VAF 15/364 reads (4%) | called by muse, mutect2
- PRKN | c.441T>C p.Y147= | Silent (SNP) | VAF 97/665 reads (15%) | called by muse, mutect2, varscan2
- PRMT3 | c.1086T>A p.I362= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, varscan2
- PRR5-ARHGAP8 | c.1152G>T p.R384= (on ENST00000352766; = p.R305= on NM_181334.5) | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- PYCARD | c.267G>C p.T89= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2
- RAI2 | c.423G>A p.P141= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs201298989; called by muse, mutect2, varscan2
- RASAL1 | c.207C>T p.A69= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs1336354879; called by muse, mutect2, varscan2
- RASAL3 | c.2301C>T p.P767= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV99653936; called by muse, mutect2
- RMDN2 | c.135G>T p.L45= | Silent (SNP) | VAF 184/527 reads (35%) | called by muse, mutect2, varscan2
- RP1L1 | c.6276G>A p.G2092= | Silent (SNP) | VAF 110/312 reads (35%) | catalogued as rs201438192; ClinVar: benign; called by muse, mutect2, varscan2
- RPN2 | c.511C>T p.L171= | Silent (SNP) | VAF 134/726 reads (18%) | catalogued as rs901725213; called by muse, mutect2, varscan2
- S1PR2 | c.525C>T p.H175= | Silent (SNP) | VAF 85/213 reads (40%) | called by muse, mutect2, varscan2
- SERPING1 | c.1233A>T p.S411= | Silent (SNP) | VAF 69/474 reads (15%) | called by muse, mutect2, varscan2
- SESN2 | c.1263C>G p.L421= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as COSV99456061; called by muse, mutect2
- SHKBP1 | c.1563C>T p.F521= | Silent (SNP) | VAF 32/396 reads (8%) | catalogued as rs150936292; called by muse, mutect2
- SLC12A2 | c.2302C>T p.L768= | Silent (SNP) | VAF 26/460 reads (6%) | catalogued as COSV99321263; called by muse, mutect2
- SLC13A1 | c.132C>G p.V44= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV52008934; called by muse, mutect2, varscan2
- SLC22A10 | c.1533T>C p.I511= | Silent (SNP) | VAF 79/449 reads (18%) | called by muse, mutect2, varscan2
- SLC35F1 | c.736C>A p.R246= | Silent (SNP) | VAF 40/363 reads (11%) | called by muse, mutect2, varscan2
- SORD | c.495C>T p.C165= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- SOX5 | c.954G>A p.L318= | Silent (SNP) | VAF 90/417 reads (22%) | catalogued as rs1428510547, COSV58637777; called by muse, mutect2, varscan2
- SPACA7 | c.45G>T p.L15= | Silent (SNP) | VAF 59/394 reads (15%) | called by muse, mutect2, varscan2
- SPON2 | c.39C>G p.A13= | Silent (SNP) | VAF 102/218 reads (47%) | called by muse, mutect2, varscan2
- SYTL3 | c.192G>T p.A64= | Silent (SNP) | VAF 36/307 reads (12%) | called by muse, mutect2, varscan2
- TAGAP | c.876C>A p.S292= | Silent (SNP) | VAF 38/237 reads (16%) | called by muse, mutect2, varscan2
- TAGAP | c.450C>A p.P150= | Silent (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- TBC1D4 | c.216C>T p.G72= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs1056857953; called by muse, mutect2, varscan2
- THY1 | c.468G>A p.T156= | Silent (SNP) | VAF 76/374 reads (20%) | catalogued as rs767420857; called by muse, mutect2, varscan2
- TMEM255A | c.192C>A p.P64= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- TMEM74B | c.327G>A p.G109= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- TRAV29DV5 | c.15G>A p.L5= | Silent (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- TRIB1 | c.832C>T p.L278= | Silent (SNP) | VAF 127/533 reads (24%) | called by muse, mutect2, varscan2
- TRUB1 | c.939A>T p.A313= | Silent (SNP) | VAF 72/284 reads (25%) | called by muse, mutect2, varscan2
- TSPAN18 | c.225G>T p.G75= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- TSPAN9 | c.177C>T p.A59= | Silent (SNP) | VAF 51/517 reads (10%) | catalogued as rs1044234564; called by muse, mutect2, varscan2
- VIRMA | c.1047A>G p.L349= | Silent (SNP) | VAF 69/254 reads (27%) | catalogued as rs1484586815, COSV52590359; called by muse, mutect2, varscan2
- VTI1A | c.543G>T p.L181= | Silent (SNP) | VAF 91/419 reads (22%) | called by muse, mutect2, varscan2
- VWA5B1 | c.447G>T p.S149= | Silent (SNP) | VAF 81/511 reads (16%) | called by muse, mutect2, varscan2
- ZAN | c.2217C>G p.T739= | Silent (SNP) | VAF 124/707 reads (18%) | catalogued as COSV100770554; called by muse, varscan2
- ZAN | c.4341C>T p.F1447= | Silent (SNP) | VAF 148/944 reads (16%) | catalogued as COSV61807425; called by muse, mutect2, varscan2
- ZFYVE28 | c.387G>A p.K129= | Silent (SNP) | VAF 102/257 reads (40%) | catalogued as COSV52111989; called by muse, mutect2, varscan2
- ZNF280A | c.96G>A p.L32= | Silent (SNP) | VAF 34/309 reads (11%) | catalogued as COSV57479944; called by muse, mutect2, varscan2
- ZNF396 | c.237C>G p.L79= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- ZNF431 | c.63G>A p.E21= | Silent (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- ZNF488 | c.774G>T p.S258= | Silent (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- ZNF536 | c.1239G>T p.V413= | Silent (SNP) | VAF 81/260 reads (31%) | catalogued as COSV100834579; called by muse, mutect2, varscan2
- ZNF676 | c.882T>C p.F294= (on ENST00000650058; = p.F262= on NM_001001411.3) | Silent (SNP) | VAF 50/401 reads (12%) | called by muse, mutect2, varscan2
- ZNF750 | c.1515G>A p.P505= | Silent (SNP) | VAF 103/294 reads (35%) | catalogued as rs762203571, COSV53960048, COSV53960176; called by muse, mutect2, varscan2
- ZP4 | c.252C>A p.S84= | Silent (SNP) | VAF 165/498 reads (33%) | catalogued as COSV63913063; called by muse, mutect2, varscan2
- ZPR1 | c.27A>T p.P9= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, varscan2
- ZW10 | c.1992C>T p.V664= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV52319262; called by muse, mutect2, varscan2
- ABCG8 | c.322+47C>T | Intron (SNP) | VAF 146/425 reads (34%) | called by muse, mutect2, varscan2
- AC073310.1 | n.265C>T | RNA (SNP) | VAF 142/388 reads (37%) | called by muse, mutect2, varscan2
- AC244258.1 | n.919G>T | RNA (SNP) | VAF 80/539 reads (15%) | catalogued as rs747082410; called by muse, mutect2, varscan2
- AGBL4 | c.*41G>T | 3'UTR (SNP) | VAF 59/401 reads (15%) | catalogued as rs1471458006; called by muse, mutect2, varscan2
- AIFM3 | c.1778+15C>G | Intron (SNP) | VAF 53/538 reads (10%) | called by muse, mutect2
- AIG1 | chr6:143339631 A>G | 3'Flank (SNP) | VAF 46/271 reads (17%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38622073 C>G | 5'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3843G>T | Intron (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- BUB3 | c.971+24G>C | Intron (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3996G>T | Intron (SNP) | VAF 62/462 reads (13%) | called by muse, mutect2, varscan2
- C19orf38 | c.-7G>A | 5'UTR (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- CAPZA3 | c.-2A>G | 5'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- CASP8 | c.1-8272C>G | Intron (SNP) | VAF 57/370 reads (15%) | catalogued as rs770582172; called by muse, mutect2, varscan2
- CD99L2 | c.-44C>G | 5'UTR (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- CLOCK | c.108-19A>G | Intron (SNP) | VAF 30/175 reads (17%) | catalogued as rs1157524267; called by muse, mutect2, varscan2
- CYP11B1 | c.239+131G>C | Intron (SNP) | VAF 26/304 reads (9%) | catalogued as COSV52830216; called by muse, mutect2
- CYP19A1 | c.*36C>T | 3'UTR (SNP) | VAF 27/398 reads (7%) | called by muse, mutect2
- DCHS2 | n.5769T>A | RNA (SNP) | VAF 18/309 reads (6%) | called by muse, mutect2
- DDB2 | c.128-36G>A | Intron (SNP) | VAF 77/448 reads (17%) | called by muse, mutect2, varscan2
- EEF1A2 | c.*3C>A | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- EPOR | chr19:11384641 C>A | 5'Flank (SNP) | VAF 46/234 reads (20%) | called by muse, mutect2, varscan2
- FAM126A | c.-205C>T | 5'UTR (SNP) | VAF 38/278 reads (14%) | catalogued as rs993639120; called by muse, mutect2, varscan2
- FOLH1B | n.1218G>C | RNA (SNP) | VAF 31/353 reads (9%) | called by muse, mutect2
- FOXL2NB | c.220+102C>G | Intron (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- FRG2KP | chr16:31569266 T>A | 5'Flank (SNP) | VAF 165/449 reads (37%) | called by muse, mutect2, varscan2
- FTSJ1 | c.958-30A>G | Intron (SNP) | VAF 64/495 reads (13%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1441+30C>T | Intron (SNP) | VAF 40/188 reads (21%) | catalogued as rs1172220235; called by muse, mutect2, varscan2
- GCSH | c.*526A>C | 3'UTR (SNP) | VAF 18/113 reads (16%) | catalogued as rs1297692698; called by muse, mutect2, varscan2
- GINM1 | c.-17T>C | 5'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- GNPTG | c.110+12C>A | Intron (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- IL17F | c.-42C>A | 5'UTR (SNP) | VAF 88/644 reads (14%) | catalogued as COSV100277177; called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27333G>A | Intron (SNP) | VAF 27/190 reads (14%) | catalogued as COSV61728578; called by muse, mutect2, varscan2
- KIR3DX1 | n.212C>T | RNA (SNP) | VAF 203/697 reads (29%) | called by muse, mutect2, varscan2
- LACTB2 | c.286+647A>G | Intron (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- LAMA1 | c.7627-44A>G | Intron (SNP) | VAF 88/338 reads (26%) | called by muse, mutect2, varscan2
- LAMA3 | c.4998+1389T>G | Intron (SNP) | VAF 86/348 reads (25%) | called by muse, mutect2, varscan2
- LILRA6 | c.-17C>A | 5'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- LOXHD1 | c.884-25C>G | Intron (SNP) | VAF 32/202 reads (16%) | catalogued as rs565055485; called by muse, mutect2, varscan2
- MAP3K5 | c.-149C>G | 5'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- MIA2 | c.1955-23C>T | Intron (SNP) | VAF 97/376 reads (26%) | catalogued as rs1318281379; called by muse, mutect2, varscan2
- MIB1 | c.1829+6075G>A | Intron (SNP) | VAF 28/356 reads (8%) | catalogued as rs1382873526; called by muse, mutect2
- MIR217 | n.12T>G | RNA (SNP) | VAF 50/134 reads (37%) | called by muse, varscan2
- NDUFB5 | c.-10C>G | 5'UTR (SNP) | VAF 54/214 reads (25%) | catalogued as rs1459618120; called by muse, mutect2, varscan2
- OR10D1P | n.318C>A | RNA (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2, varscan2
- PCAT19 | n.1275G>C | RNA (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- PCDH10 | c.*31T>A | 3'UTR (SNP) | VAF 65/239 reads (27%) | called by muse, mutect2, varscan2
- PDE1A | c.*15A>C | 3'UTR (SNP) | VAF 72/364 reads (20%) | called by muse, varscan2
- PDE2A | c.324-944dup | Intron (INS) | VAF 66/534 reads (12%) | called by mutect2, pindel, varscan2
- PDZD11 | c.-13-65C>T | Intron (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- PGC | c.*30C>G | 3'UTR (SNP) | VAF 60/1337 reads (4%) | called by muse, mutect2
- PHF23 | c.-1G>A | 5'UTR (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.1376-4532C>G | Intron (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30057222 C>G | 5'Flank (SNP) | VAF 43/530 reads (8%) | called by muse, mutect2
- POU2F2 | c.303+6547A>T | Intron (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- PSMC3IP | c.338-224C>A | Intron (SNP) | VAF 54/107 reads (50%) | called by muse, varscan2
- PTDSS1 | c.*189G>T | 3'UTR (SNP) | VAF 36/154 reads (23%) | catalogued as rs1337737845; called by muse, mutect2, varscan2
- QARS1 | c.266-12C>G | Intron (SNP) | VAF 78/532 reads (15%) | called by muse, mutect2, varscan2
- RAB18 | c.*2075G>T | 3'UTR (SNP) | VAF 65/408 reads (16%) | called by muse, mutect2, varscan2
- RALGPS2 | c.*7G>T | 3'UTR (SNP) | VAF 116/396 reads (29%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-712G>T | Intron (SNP) | VAF 51/337 reads (15%) | called by muse, mutect2, varscan2
- RNF168 | c.-49C>G | 5'UTR (SNP) | VAF 27/576 reads (5%) | catalogued as COSV100535171; called by muse, mutect2
- RNU6-1224P | chr8:102529367 G>T | 3'Flank (SNP) | VAF 39/209 reads (19%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892431 C>T | 5'Flank (SNP) | VAF 51/309 reads (17%) | called by muse, mutect2, varscan2
- RPS19BP1 | c.181+26G>T | Intron (SNP) | VAF 52/269 reads (19%) | called by muse, mutect2, varscan2
- SCEL | c.1037+13C>T | Intron (SNP) | VAF 36/303 reads (12%) | catalogued as rs1382730482; called by muse, mutect2, varscan2
- SCP2D1 | chr20:18810108 G>T | 5'Flank (SNP) | VAF 24/68 reads (35%) | called by muse, varscan2
- SNORD115-43 | n.74C>A | RNA (SNP) | VAF 93/420 reads (22%) | called by muse, mutect2, varscan2
- STIMATE | chr3:52836647 C>A | 3'Flank (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- SVIL | c.3516+4364G>T | Intron (SNP) | VAF 54/457 reads (12%) | called by muse, mutect2, varscan2
- TCN1 | c.-4A>G | 5'UTR (SNP) | VAF 102/555 reads (18%) | called by muse, mutect2, varscan2
- TFR2 | c.849+50C>G | Intron (SNP) | VAF 25/400 reads (6%) | catalogued as rs1425416592; called by muse, mutect2
- TJP3 | c.-9-16C>T | Intron (SNP) | VAF 58/220 reads (26%) | catalogued as rs573607278; called by muse, mutect2, varscan2
- TRIM61 | c.526-2212C>G | Intron (SNP) | VAF 25/520 reads (5%) | called by muse, mutect2
- TTN | c.34265-4188A>C | Intron (SNP) | VAF 42/238 reads (18%) | catalogued as COSV60308876; called by mutect2, varscan2
- TTN | c.10360+4423G>C | Intron (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
- TTN | c.10360+4114G>C | Intron (SNP) | VAF 33/561 reads (6%) | catalogued as COSV59933745, COSV60132056; called by muse, mutect2
- UBBP4 | n.595C>T | RNA (SNP) | VAF 134/467 reads (29%) | called by muse, mutect2, varscan2
- VPS35L | c.434-718A>G | Intron (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- YAF2 | c.152+1619G>A | Intron (SNP) | VAF 36/362 reads (10%) | called by muse, mutect2
- ZEB1 | c.58+44029G>T | Intron (SNP) | VAF 36/368 reads (10%) | called by muse, mutect2, varscan2
- ZNF117 | c.-13A>T | 5'UTR (SNP) | VAF 54/562 reads (10%) | called by muse, mutect2
- ZNF525 | c.142+372dup | Intron (INS) | VAF 38/363 reads (10%) | called by mutect2, pindel, varscan2
- ZNF658B | n.1260A>G | RNA (SNP) | VAF 116/1032 reads (11%) | called by muse, mutect2, varscan2
